Somatic mutation profile of tumor specimen ALCH-ADBW-TTP1-A (aliquot ALCH-ADBW-TTP1-A-1-0-D-A517-36) from ALCHEMIST case ALCH-ADBW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.2 years (19,422 days).
Specimen ALCH-ADBW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf1257d0-7121-4891-a49b-10f4ea4f218a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADBW-NB1-A (Blood Derived Normal), aliquot ALCH-ADBW-NB1-A-1-0-D-A517-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc288d39-f4eb-43e7-b35c-2b4d6e8d77d3

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, RNA 3, 3'UTR 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BDP1 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1463769239; called by muse, mutect2
- DVL2 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs771212668; called by muse, mutect2, varscan2
- FAM47A | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs764123221, COSV60495125; called by muse, mutect2, varscan2
- FTMT | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs781372421, COSV58420806; called by muse, mutect2, varscan2
- GABRB1 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99782520; called by muse, mutect2
- OR5D14 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 74/521 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100162591, COSV59455986; called by muse, mutect2, varscan2
- RFX3 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 55/442 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV65862883; called by muse, mutect2, varscan2
- RIC1 | c.516G>C p.M172I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV52605171; called by muse, mutect2
- RIC1 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1365151061, COSV99316628; called by muse, varscan2
- TARBP2 | c.449_450del p.P150Rfs*7 (on ENST00000266987 / NM_134323.2; = p.P129Rfs*7 on NM_004178.4) | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | catalogued as rs758159322; called by mutect2, pindel, varscan2
- ARHGAP30 | c.2956C>T p.R986* (on ENST00000368013 / NM_001025598.2; = p.R775* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- DDX18 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 75/530 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EXT1 | c.1508C>A p.A503D | Missense Mutation (SNP) | VAF 77/564 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MYOF | c.4306_4309dup p.P1437Qfs*7 | Frame Shift Ins (INS) | VAF 23/203 reads (11%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.2083-4_2087delinsTTTTTTTTT p.X695_splice | Splice Site (ONP) | VAF 12/128 reads (9%) | called by mutect2*, pindel
- PLEKHG6 | c.105del p.G36Afs*37 | Frame Shift Del (DEL) | VAF 17/166 reads (10%) | called by mutect2, pindel*
- RIC1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2
- RIC1 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, varscan2
- SLC19A2 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 81/561 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- SRRM2 | c.4991A>T p.K1664I | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); called by muse, mutect2
- STK33 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 40/447 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2
- STON1-GTF2A1L | c.2854G>T p.V952L | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.06); called by muse, mutect2
- TCF12 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2
- ZNF727 | c.514T>A p.C172S | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRYL | c.3540C>T p.G1180= | Silent (SNP) | VAF 60/773 reads (8%) | called by muse, mutect2
- RGL1 | c.1002A>G p.A334= (on ENST00000360851 / NM_001297672.2; = p.A369= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/337 reads (11%) | called by muse, mutect2, varscan2
- RIC1 | c.597G>A p.L199= | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, varscan2
- AP001425.1 | chr21:38208373 C>T | 5'Flank (SNP) | VAF 57/473 reads (12%) | called by muse, mutect2, varscan2
- BCAR4 | n.1106C>T | RNA (SNP) | VAF 58/553 reads (10%) | catalogued as rs1464506796; called by muse, varscan2
- IGHMBP2 | c.*17A>T | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- NAPSB | n.815G>A | RNA (SNP) | VAF 29/187 reads (16%) | catalogued as rs188342506; called by muse, mutect2, varscan2
- UBR7 | c.*848C>A | 3'UTR (SNP) | VAF 17/401 reads (4%) | called by muse, mutect2
- ZNF252P | n.255del | RNA (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
